CGCI case BLGSP-71-08-00035 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a6c47b1-6130-4824-b521-cc64523bc1f2

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Dead.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 5.4 years (1,956 days); Year of diagnosis: 2014; Method of diagnosis: Core Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 97 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Sites of involvement: Liver.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 40; ECOG performance status: 4.
- Days to follow up: 97 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -1.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.

Other clinical attributes
- Day -1: Risk factors: HIV/AIDS.
- Day -1: Comorbidities: HIV/AIDS.
- Day 0: Weight: 17 kg; Height: 106 cm; BMI: 15.1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-08-00035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: Frozen; Days to sample procurement: -1 day; Method of sample procurement: Needle Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-08-00035-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-08-00035-01-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-08-00035-01B-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 50; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-08-00035-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 45; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-08-00035-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-08-00035-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: -1 day; Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
